Somatic mutation profile of cancer-model specimen HCM-BROD-0029-C71-85C (3D Neurosphere, passage 7; aliquot HCM-BROD-0029-C71-85C-01D-A80U-36), derived from the recurrence tumor of HCMI case HCM-BROD-0029-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.0 years (21,192 days).
Specimen HCM-BROD-0029-C71-85C: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df2b5528-cc02-4116-937e-b4ed2e4409e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0029-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0029-C71-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffe170f5-48df-4e54-8219-c0f02c6f1dda

The open-access MAF lists 86 somatic variants for this specimen: 62 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 22, Frame Shift Del 7, Intron 2, In Frame Del 2, Splice Region 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 141/261 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AFM | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 151/362 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769742032; called by muse, mutect2, varscan2
- ASS1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 216/389 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs373239430; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C1orf68 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 204/366 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs553642846; called by muse, mutect2, varscan2
- C4B | c.3701C>T p.T1234I | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs750410876; called by mutect2, varscan2
- CDC20 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 137/297 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371111819; called by muse, mutect2, varscan2
- COL6A2 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 252/507 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs142880107; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDR2 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 187/370 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759709680, COSV63370740, COSV63375402; called by muse, mutect2, varscan2
- DYRK1A | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 18/386 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs1569363929; called by muse, mutect2
- GCM2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 17/454 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs979559861, COSV65276222; called by muse, mutect2
- KCNG2 | c.1363_1365del p.D455del | In Frame Del (DEL) | VAF 224/492 reads (46%) | catalogued as rs1032453831; called by pindel, varscan2
- LOXHD1 | c.6614G>A p.R2205H (on ENST00000642948; = p.R2143H on NM_144612.7) | Missense Mutation (SNP) | VAF 216/460 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.399); catalogued as rs531043544, COSV56067084; called by muse, varscan2
- LRRC43 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 172/619 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs758327800, COSV60289293; called by muse, mutect2, varscan2
- LZTR1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 223/495 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1390048261, CD151200, COSV53147042, COSV53148013; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRK | c.238G>T p.G80W | Missense Mutation (SNP) | VAF 153/154 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1407667614; called by muse, mutect2, varscan2
- OR52K2 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 194/447 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs757200117, COSV57835270; called by muse, mutect2, varscan2
- ORMDL1 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 195/409 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1344520389; called by muse, mutect2, varscan2
- PDZD2 | c.6911C>T p.T2304M | Missense Mutation (SNP) | VAF 129/261 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.732); catalogued as rs771660997; called by muse, mutect2, varscan2
- POU6F2 | c.1122G>T p.Q374H | Missense Mutation (SNP) | VAF 22/826 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101302829; called by muse, mutect2
- RBBP8NL | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 313/919 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752143359; called by muse, mutect2, varscan2
- RGS20 | c.845C>T p.T282I (on ENST00000297313 / NM_170587.4; = p.T135I on NM_003702.4) | Missense Mutation (SNP) | VAF 92/200 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs144684508; called by muse, mutect2, varscan2
- SLC16A5 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 232/449 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.075); catalogued as rs372714521, COSV104395527; called by muse, mutect2, varscan2
- SPG11 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 159/353 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as rs764680914, COSV55990571; called by muse, mutect2, varscan2
- TJP3 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 139/271 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as rs146857520; called by muse, mutect2, varscan2
- TXNDC2 | c.227G>A p.R76H (on ENST00000306084 / NM_001098529.2; = p.R9H on NM_032243.6) | Missense Mutation (SNP) | VAF 184/369 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.392); catalogued as rs183239518, COSV60152030; called by muse, mutect2, varscan2
- ZNF560 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 179/437 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs377042499; called by muse, mutect2, varscan2
- ABCA7 | c.5306T>A p.L1769Q | Missense Mutation (SNP) | VAF 179/351 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- AHCYL1 | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 130/310 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ARHGAP5 | c.3943G>T p.D1315Y (on ENST00000345122 / NM_001030055.2; = p.D1314Y on NM_001173.3) | Missense Mutation (SNP) | VAF 99/106 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- ATG2B | c.4142_4161+15del p.X1381_splice | Splice Site (DEL) | VAF 86/200 reads (43%) | called by mutect2, pindel, varscan2
- ATP8B1 | c.1010T>C p.M337T | Missense Mutation (SNP) | VAF 80/182 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- B3GNT4 | c.46del p.R16Gfs*34 | Frame Shift Del (DEL) | VAF 136/493 reads (28%) | called by pindel, varscan2
- C20orf144 | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 22/482 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CEP85L | c.1359_1362del p.E454Ffs*12 | Frame Shift Del (DEL) | VAF 122/211 reads (58%) | called by pindel, varscan2
- CNTNAP2 | c.1017C>A p.S339R | Missense Mutation (SNP) | VAF 148/530 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CPPED1 | c.570C>A p.S190R | Missense Mutation (SNP) | VAF 14/455 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2
- CSN3 | c.26del p.N9Mfs*5 | Frame Shift Del (DEL) | VAF 84/223 reads (38%) | called by mutect2, pindel, varscan2
- DNAH7 | c.8911G>T p.D2971Y | Missense Mutation (SNP) | VAF 16/372 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAT1 | c.8705C>A p.A2902D | Missense Mutation (SNP) | VAF 174/368 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by mutect2, varscan2
- GALK2 | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 88/189 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- IVL | c.1388T>C p.L463P | Missense Mutation (SNP) | VAF 18/552 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.02); called by muse, mutect2
- LRRC4B | c.1227C>A p.Y409* | Nonsense Mutation (SNP) | VAF 261/510 reads (51%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.610C>T p.H204Y | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MROH2B | c.3867C>A p.L1289= | Splice Region (SNP) | VAF 117/224 reads (52%) | called by muse, mutect2, varscan2
- MUC1 | c.2917del p.S973Qfs*138 (on ENST00000611571 / NM_001371720.1; = p.S186Qfs*138 on NM_001204285.2) | Frame Shift Del (DEL) | VAF 255/680 reads (38%) | called by mutect2, pindel, varscan2
- NID2 | c.2877C>A p.H959Q | Missense Mutation (SNP) | VAF 163/163 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- NOL8 | c.335del p.G112Vfs*6 | Frame Shift Del (DEL) | VAF 203/505 reads (40%) | called by mutect2, pindel, varscan2
- NRDC | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 132/268 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR52I1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 218/478 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.415); called by muse, varscan2
- PDILT | c.1627A>G p.K543E | Missense Mutation (SNP) | VAF 213/405 reads (53%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PEG3 | c.3887A>G p.E1296G | Missense Mutation (SNP) | VAF 222/435 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- PIK3R4 | c.814T>A p.F272I | Missense Mutation (SNP) | VAF 116/243 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- SPATC1 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 284/613 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TBC1D22B | c.564del p.K188Nfs*13 | Frame Shift Del (DEL) | VAF 76/293 reads (26%) | called by mutect2, pindel, varscan2
- TENM2 | c.3406G>T p.V1136L (on ENST00000518659 / NM_001122679.2; = p.V904L on NM_001080428.3) | Missense Mutation (SNP) | VAF 97/187 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- THAP2 | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 249/400 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TLR7 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNKS | c.3345_3350del p.D1115_K1116del | In Frame Del (DEL) | VAF 79/239 reads (33%) | called by mutect2, pindel, varscan2
- TRIM77 | c.962A>C p.N321T | Missense Mutation (SNP) | VAF 186/353 reads (53%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT2A3 | c.1267T>A p.L423I | Missense Mutation (SNP) | VAF 149/324 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- UTP14C | c.1247_1256del p.E416Gfs*40 | Frame Shift Del (DEL) | VAF 95/311 reads (31%) | called by mutect2, pindel, varscan2
- WNK2 | c.5482G>A p.A1828T (on ENST00000297954 / NM_001282394.1; = p.A1791T on NM_006648.3) | Missense Mutation (SNP) | VAF 384/802 reads (48%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.701); called by muse, mutect2
- ABHD17B | c.690T>C p.I230= | Silent (SNP) | VAF 128/264 reads (48%) | catalogued as rs756745882; called by muse, mutect2, varscan2
- APOL2 | c.723A>G p.P241= | Silent (SNP) | VAF 211/451 reads (47%) | called by muse, mutect2, varscan2
- BCL11A | c.888G>A p.P296= (on ENST00000335712 / NM_001365609.1; = p.P330= on NM_018014.4) | Silent (SNP) | VAF 223/452 reads (49%) | catalogued as rs747182714; called by muse, mutect2, varscan2
- COL8A1 | c.1086G>A p.R362= | Silent (SNP) | VAF 13/493 reads (3%) | called by muse, mutect2
- CR2 | c.2577C>T p.N859= | Silent (SNP) | VAF 136/278 reads (49%) | catalogued as rs776361702, COSV65505901; ClinVar: likely benign; called by muse, mutect2, varscan2
- CRLF1 | c.276C>T p.N92= | Silent (SNP) | VAF 256/569 reads (45%) | catalogued as rs775994224, COSV66505392, COSV66505845; called by muse, mutect2, varscan2
- CT45A3 | c.435C>T p.F145= | Silent (SNP) | VAF 25/134 reads (19%) | called by muse, mutect2
- DEPDC1 | c.2382A>G p.T794= (on ENST00000456315 / NM_001114120.3; = p.T510= on NM_017779.6) | Silent (SNP) | VAF 207/382 reads (54%) | called by muse, mutect2, varscan2
- DNAH7 | c.2994C>T p.D998= | Silent (SNP) | VAF 158/330 reads (48%) | called by muse, mutect2, varscan2
- FAT1 | c.8706C>A p.A2902= | Silent (SNP) | VAF 174/368 reads (47%) | called by mutect2, varscan2
- ITGAM | c.909C>T p.I303= | Silent (SNP) | VAF 144/322 reads (45%) | catalogued as rs374273074; called by muse, mutect2, varscan2
- JCAD | c.2889C>T p.N963= | Silent (SNP) | VAF 221/435 reads (51%) | catalogued as rs769402502; called by muse, mutect2, varscan2
- KCNH7 | c.3040C>A p.R1014= | Silent (SNP) | VAF 13/442 reads (3%) | catalogued as COSV59793884; called by muse, mutect2
- NCAPH | c.504C>T p.R168= | Silent (SNP) | VAF 155/345 reads (45%) | catalogued as rs770891599; called by muse, mutect2, varscan2
- OR13C8 | c.42G>A p.L14= | Silent (SNP) | VAF 21/405 reads (5%) | called by muse, mutect2
- ORM1 | c.99C>T p.N33= | Silent (SNP) | VAF 100/342 reads (29%) | catalogued as rs759696863; called by muse, mutect2
- PARP15 | c.708G>A p.P236= | Silent (SNP) | VAF 158/350 reads (45%) | catalogued as rs368678964; called by muse, mutect2, varscan2
- SLC3A2 | c.1164C>T p.I388= | Silent (SNP) | VAF 146/298 reads (49%) | catalogued as rs756682904; called by muse, mutect2, varscan2
- TRPM2 | c.384C>T p.G128= | Silent (SNP) | VAF 177/332 reads (53%) | catalogued as rs143653746; called by muse, mutect2, varscan2
- VPS33A | c.1371G>A p.T457= | Silent (SNP) | VAF 196/641 reads (31%) | catalogued as rs754744464, COSV57355859, COSV99931261; called by muse, mutect2, varscan2
- WHAMM | c.1746G>T p.A582= | Silent (SNP) | VAF 22/441 reads (5%) | catalogued as rs371290123, COSV54495591; called by muse, mutect2
- ZAR1L | c.450C>T p.D150= | Silent (SNP) | VAF 294/572 reads (51%) | called by muse, mutect2, varscan2
- NEDD4L | c.297+3907C>T | Intron (SNP) | VAF 370/738 reads (50%) | catalogued as rs1000425094; called by muse, mutect2, varscan2
- ZNF783 | c.802+3363G>A | Intron (SNP) | VAF 297/989 reads (30%) | called by muse, mutect2, varscan2
